CCDI case PBCJHZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/30a3ae5f-3257-4346-9702-3c74453c2424

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 14.0 years (5,104 days).

Biospecimens (3 samples)
- Sample 0DT7WH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DT7WU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DT7X6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
